Somatic mutation profile of tumor specimen TARGET-30-PARBGP-01A (aliquot TARGET-30-PARBGP-01A-01D) from TARGET case TARGET-30-PARBGP, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 9.9 years (3,625 days).
Specimen TARGET-30-PARBGP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9a2fdb9-ed8e-430f-957a-3ea0b8e91d04.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARBGP-10A (Blood Derived Normal), aliquot TARGET-30-PARBGP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c8b41aa-5392-4c78-b3da-047841b3bce0

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 13, Silent 5, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH18A1 | c.1730T>A p.M577K | Missense Mutation (SNP) | VAF 84/189 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV64662416; called by muse, mutect2, varscan2
- AMBRA1 | c.1178G>A p.R393H (on ENST00000458649 / NM_001367468.1; = p.R303H on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as rs773779272, COSV100095420; called by muse, mutect2, varscan2
- CCNF | c.2274C>G p.S758R | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV53539211; called by muse, mutect2, varscan2
- COL11A1 | c.2376G>T p.M792I | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.885); catalogued as COSV100614872, COSV62179317; called by mutect2, varscan2
- COL12A1 | c.2933C>A p.T978N | Missense Mutation (SNP) | VAF 65/135 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV59393190; called by muse, mutect2, varscan2
- HCN1 | c.1447T>G p.F483V | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV57503190; called by muse, mutect2, varscan2
- OR2T1 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1053720561, COSV63541643; called by muse, mutect2, varscan2
- PELI1 | c.659A>G p.E220G | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV62729834; called by mutect2, varscan2
- PHF21A | c.701T>C p.V234A (on ENST00000418153 / NM_001101802.3; = p.V235A on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57652189; called by muse, mutect2, varscan2
- RAF1 | c.1189C>G p.L397V | Missense Mutation (SNP) | VAF 38/42 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52577051; called by muse, mutect2, varscan2
- SELENOO | c.754A>G p.I252V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as rs536146930, COSV66598874; called by muse, mutect2, varscan2
- TJP3 | c.949C>A p.Q317K | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV53661545; called by muse, mutect2, varscan2
- ARHGAP5 | c.2168del p.N723Tfs*8 | Frame Shift Del (DEL) | VAF 26/59 reads (44%) | called by mutect2, pindel, varscan2
- FSCB | c.1094C>A p.A365D | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2
- OR3A1 | c.132C>A p.G44= | Silent (SNP) | VAF 42/83 reads (51%) | catalogued as COSV60162905; called by muse, mutect2, varscan2
- PRKD1 | c.2634G>T p.L878= | Silent (SNP) | VAF 32/122 reads (26%) | catalogued as COSV59564150; called by muse, mutect2, varscan2
- RTN4RL2 | c.1158C>G p.P386= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV58651658, COSV58651992; called by muse, mutect2, varscan2
- STAMBPL1 | c.369C>T p.N123= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs764859212, COSV64222415; called by muse, mutect2, varscan2
- UPF2 | c.3468G>T p.L1156= | Silent (SNP) | VAF 77/681 reads (11%) | catalogued as COSV62659771; called by muse, mutect2, varscan2
